Somatic mutation profile of tumor specimen TARGET-10-PATWNL-09A (aliquot TARGET-10-PATWNL-09A-01D) from TARGET case TARGET-10-PATWNL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (633 days).
Specimen TARGET-10-PATWNL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 928e6492-f146-42c3-8f37-f96ad5dba66c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATWNL-10A (Blood Derived Normal), aliquot TARGET-10-PATWNL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a7f6382-7be5-43b5-b67d-8a970e137100

The open-access MAF lists 25 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 7, Frame Shift Ins 2, 5'Flank 2, Intron 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AWAT1 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs756595258, COSV65738239; called by muse, mutect2, varscan2
- CRB2 | c.1849G>A p.G617R | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs760937283, COSV63501925; called by muse, mutect2, varscan2
- KCNQ5 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1278071689, COSV59651184; called by muse, mutect2
- MARCHF9 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147077505; called by muse, mutect2, varscan2
- MYB | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV57196169, COSV57200862; called by muse, mutect2, varscan2
- PLXNA4 | c.3817C>T p.R1273W | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs901328356, COSV58107669; called by muse, mutect2, varscan2
- RALGAPA1 | c.3175G>A p.D1059N | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51881652; called by muse, mutect2, varscan2
- SHROOM2 | c.3529G>T p.A1177S | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.354); catalogued as COSV66604925, COSV66611266; called by mutect2, varscan2
- TBATA | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54717397; called by muse, mutect2
- VCPIP1 | c.2532C>A p.D844E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV60046124; called by muse, mutect2, varscan2
- EZH2 | c.2201dup p.K735Efs*23 (on ENST00000460911 / NM_001203247.2; = p.K740Efs*23 on NM_004456.5) | Frame Shift Ins (INS) | VAF 12/16 reads (75%) | called by mutect2, varscan2*
- LEF1 | c.885_886insT p.R296* | Frame Shift Ins (INS) | VAF 28/60 reads (47%) | called by mutect2, pindel*, varscan2
- NOTCH1 | c.4744_4746del p.P1582del | In Frame Del (DEL) | VAF 12/24 reads (50%) | called by pindel, varscan2
- ADAM18 | c.399A>C p.S133= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- CAPN14 | c.1254C>T p.L418= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs374988264; called by muse, mutect2, varscan2
- DMAC2L | c.555C>T p.A185= | Silent (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.5790C>T p.F1930= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV64140559; called by muse, mutect2, varscan2
- JADE3 | c.1521C>T p.F507= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs145597232, COSV54470337; called by muse, mutect2, varscan2
- PLEC | c.10341C>T p.A3447= (on ENST00000322810 / NM_201380.4; = p.A3337= on NM_000445.5) | Silent (SNP) | VAF 40/73 reads (55%) | called by muse, mutect2, varscan2
- ZNF619 | c.1542C>T p.P514= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs776571678; called by muse, mutect2, varscan2
- AC008758.3 | n.338C>A | RNA (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- ATRX | c.4810-41dup | Intron (INS) | VAF 9/26 reads (35%) | catalogued as rs782111058; called by mutect2, varscan2
- CCNC | chr6:99568720 T>A | 5'Flank (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- INPP5J | chr22:31122965 T>C | 5'Flank (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- MAPK12 | c.619+63C>A | Intron (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
